TCGA case TCGA-VD-A8KE — Uveal Melanoma (TCGA-UVM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa; Tissue source site: University of Liverpool. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c9bfc2a7-0914-4080-a0a3-1c6a4e58e1ab

Demographics
Sex at birth: female; Country of residence at enrollment: United Kingdom; Age at index: 74 years; Vital status: Alive.

Diagnoses (1)
1. Mixed epithelioid and spindle cell melanoma: ICD-O-3 morphology code: 8770/3; ICD-10 code: C69.30; Tissue or organ of origin: Choroid; Site of resection or biopsy: Choroid; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 74.7 years (27,290 days); Year of diagnosis: 2012; Method of diagnosis: Enucleation; AJCC staging edition: 7th; AJCC clinical T: T2a; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IIA; AJCC pathologic T: T2a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 821 days (2.2 years); Sites of involvement: Eye, Choroid.
   Pathology details: Measurement type: Echographic; Tumor basal diameter: 10.8.
   Pathology details: Additional pathology findings: Extravascular Matrix Loops; Consistent pathology review: Yes; Epithelioid cell percent range: 31-60%; Extrascleral extension present: No; Measurement type: Echographic; Spindle cell percent range: 31-60%; Tumor depth measurement: 8.4; Tumor infiltrating lymphocytes: Few; Tumor shape: Mushroom.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 6 days; Disease response: Tumor Free.
- Days to follow up: 821 days (2.2 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Test (Microscopy, NOS): Mitotic Count Reported; Mitotic count: 3.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VD-A8KE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 20 mg.
  Slide TCGA-VD-A8KE-01Z-00-DX1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 50; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-VD-A8KE-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Samples TCGA-VD-A8KE-10A, TCGA-VD-A8KE-10B (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology, Tumor morphology list, Tumor morphology 1: Histologic diagnosis: Epithelioid Cell.
- Primary pathology, Tumor morphology list, Tumor morphology 2: Histologic diagnosis: Spindle Cell.
- Primary pathology: Extravascular matrix patterns: Loops; Tumor basal diameter mx: Echographic Measurement; Tumor thickness measurement: Echographic Measurement.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 821 days; disease-specific survival: no event (censored), 821 days; progression-free interval: no event (censored), 821 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VD-A8KE-01A-11D-A39V-01): tumor purity 0.96, ploidy 2.11, whole-genome doublings 0.
